Somatic mutation profile of tumor specimen TCGA-BR-A4QI-01A (aliquot TCGA-BR-A4QI-01A-12D-A25D-08) from TCGA case TCGA-BR-A4QI, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 71.0 years (25,928 days).
Specimen TCGA-BR-A4QI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1da80720-b6d0-451e-850a-933a8810c2c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-A4QI-10A (Blood Derived Normal), aliquot TCGA-BR-A4QI-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8647a312-3252-4321-abb5-f8bbb7cf8ec0

The open-access MAF lists 135 somatic variants for this specimen: 100 protein-altering or splice-affecting, 33 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 92, Silent 33, In Frame Del 2, Frame Shift Del 2, Nonsense Mutation 2, Frame Shift Ins 1, RNA 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 41/55 reads (75%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACHE | c.1036C>A p.L346I | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV53816242; called by muse, mutect2
- ADAMTS16 | c.811T>A p.Y271N | Missense Mutation (SNP) | VAF 46/186 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56982938; called by muse, mutect2, varscan2
- AHDC1 | c.1778A>G p.K593R | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99899705; called by muse, mutect2, varscan2
- ANK2 | c.2051A>G p.K684R | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.135); catalogued as COSV52152261; called by muse, mutect2, varscan2
- ANKRD44 | c.2474G>T p.G825V | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.53); catalogued as rs1253530646, COSV56551433; called by muse, mutect2, varscan2
- APBB1IP | c.1093T>C p.Y365H | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66131088; called by muse, mutect2, varscan2
- APBB3 | c.853A>C p.S285R (on ENST00000357560 / NM_133173.2; = p.S292R on NM_006051.3) | Missense Mutation (SNP) | VAF 119/238 reads (50%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV60051866; called by muse, mutect2, varscan2
- ASB1 | c.548G>T p.R183L | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.059); catalogued as rs370724967, COSV99223222; called by muse, mutect2, varscan2
- BCL2L14 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53784912; called by muse, mutect2, varscan2
- BMPER | c.1154C>T p.T385M | Missense Mutation (SNP) | VAF 55/203 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs560058928, COSV51814255; called by muse, mutect2, varscan2
- BRINP3 | c.773C>A p.A258E | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV66517414; called by muse, mutect2, varscan2
- C2orf68 | c.341C>G p.A114G | Missense Mutation (SNP) | VAF 10/288 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.514); catalogued as COSV100108362, COSV60472619; called by muse, mutect2
- CARS2 | c.707A>T p.K236I | Missense Mutation (SNP) | VAF 39/72 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57284911; called by muse, mutect2, varscan2
- CCDC114 | c.985C>T p.R329C | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs769393527, COSV59555921; called by muse, mutect2, varscan2
- CD1C | c.155A>T p.E52V | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV63805992; called by muse, mutect2, varscan2
- CDC6 | c.469T>A p.Y157N | Missense Mutation (SNP) | VAF 18/378 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52930050; called by muse, mutect2
- CHERP | c.685C>T p.Q229* | Nonsense Mutation (SNP) | VAF 13/68 reads (19%) | catalogued as COSV52223196; called by muse, mutect2, varscan2
- CRIP2 | c.518A>G p.Y173C | Missense Mutation (SNP) | VAF 17/171 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs1327614106, COSV61274037; called by muse, mutect2, varscan2
- CUBN | c.9347A>T p.K3116M | Missense Mutation (SNP) | VAF 23/193 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.564); catalogued as COSV100912810, COSV64711051; called by muse, mutect2, varscan2
- CWH43 | c.335G>T p.W112L | Missense Mutation (SNP) | VAF 59/95 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV56937318; called by muse, mutect2, varscan2
- DIDO1 | c.4685A>T p.Q1562L | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as COSV56616931; called by muse, mutect2, varscan2
- DMC1 | c.190G>A p.G64R | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53258612, COSV53259246; called by muse, mutect2, varscan2
- DOCK11 | c.3471+1G>C p.X1157_splice | Splice Site (SNP) | VAF 13/87 reads (15%) | catalogued as COSV52235782; called by muse, mutect2, varscan2
- DRAM1 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.65); PolyPhen benign (0.017); catalogued as COSV51596938; called by muse, mutect2, varscan2
- DSG4 | c.1294G>A p.D432N | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.601); catalogued as COSV57389501; called by muse, mutect2, varscan2
- EIF5AL1 | c.265T>C p.F89L | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.229); catalogued as COSV73122962; called by muse, mutect2, varscan2
- ENPP1 | c.1490A>C p.K497T | Missense Mutation (SNP) | VAF 121/286 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62931124; called by muse, mutect2, varscan2
- FAM161A | c.1484G>A p.R495H | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs201998260, COSV56764939; called by muse, mutect2, varscan2
- FLACC1 | c.58C>T p.R20W | Missense Mutation (SNP) | VAF 54/99 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as rs759419207, COSV53782788; called by muse, mutect2, varscan2
- FLRT2 | c.1712G>A p.R571H | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.912); catalogued as rs775899415, COSV58137970, COSV58139384; called by muse, mutect2, varscan2
- FRMD3 | c.1469A>C p.E490A | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0.01); catalogued as COSV58457048, COSV58468598; called by muse, mutect2, varscan2
- GPM6A | c.41G>T p.C14F | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54536476; called by muse, mutect2, varscan2
- GYG1 | c.820G>A p.V274I | Missense Mutation (SNP) | VAF 57/92 reads (62%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV56049116; called by muse, mutect2, varscan2
- GYS2 | c.2032C>T p.R678W | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.719); catalogued as rs908505998, COSV53921128, COSV53926841; called by muse, mutect2, varscan2
- HRNR | c.1813G>C p.G605R | Missense Mutation (SNP) | VAF 136/412 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs773575558, COSV64255895; called by muse, mutect2, varscan2
- HTR3B | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.4); PolyPhen probably damaging (1); catalogued as COSV52743407; called by muse, mutect2, varscan2
- ITPRID1 | c.2597A>T p.E866V | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV60071935; called by muse, mutect2, varscan2
- ITSN2 | c.2729C>T p.T910I | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.939); catalogued as COSV61945014; called by muse, mutect2, varscan2
- KCNAB3 | c.517A>G p.S173G | Missense Mutation (SNP) | VAF 41/351 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs768326613, COSV58049994; called by muse, mutect2, varscan2
- LRIT1 | c.611C>A p.A204E | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV64512148; called by muse, mutect2, varscan2
- LRP1B | c.13304A>C p.K4435T | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as COSV101254879, COSV67186665, COSV67220594; called by muse, mutect2, varscan2
- LTK | c.200C>A p.S67Y | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV55489749; called by muse, mutect2, varscan2
- MAGEA3 | c.766C>G p.L256V | Missense Mutation (SNP) | VAF 28/253 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV64755920; called by muse, mutect2, varscan2
- MITD1 | c.43G>T p.A15S | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV56806109; called by muse, mutect2, varscan2
- MLX | c.599C>T p.T200M | Missense Mutation (SNP) | VAF 23/174 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.029); catalogued as rs1048805920, COSV53816567; called by muse, mutect2, varscan2
- MRPL43 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as COSV52967004; called by muse, mutect2, varscan2
- MSN | c.1122A>C p.E374D | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.38); PolyPhen benign (0.033); catalogued as COSV64303610; called by muse, mutect2, varscan2
- MTREX | c.1499A>G p.N500S | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV57924576; called by muse, mutect2, varscan2
- MTUS2 | c.2983C>T p.R995W | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764265852, COSV70913437; called by muse, mutect2, varscan2
- MUC16 | c.27675G>T p.M9225I | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV67454081; called by muse, mutect2, varscan2
- MUC17 | c.2791G>A p.D931N | Missense Mutation (SNP) | VAF 94/950 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV60283487, COSV60284853; called by muse, mutect2
- MYPN | c.515G>C p.R172T | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV62732408; called by muse, mutect2
- NBAS | c.2989G>A p.E997K | Missense Mutation (SNP) | VAF 31/176 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as rs201150984, COSV55716214; called by muse, mutect2, varscan2
- NECTIN4 | c.176G>A p.G59D | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.51); PolyPhen benign (0.012); catalogued as rs142201196; called by muse, mutect2, varscan2
- NIBAN2 | c.971G>A p.R324Q | Missense Mutation (SNP) | VAF 171/480 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.966); catalogued as rs778880991, COSV64824016, COSV64825083; called by muse, mutect2, varscan2
- NPAP1 | c.1502C>G p.P501R | Missense Mutation (SNP) | VAF 70/185 reads (38%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.84); catalogued as COSV61503861, COSV61505487; called by muse, mutect2, varscan2
- NWD1 | c.2582G>A p.R861Q | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs371438099, COSV100343818; called by muse, mutect2, varscan2
- OR10K2 | c.292G>T p.A98S | Missense Mutation (SNP) | VAF 70/165 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as COSV59220714; called by muse, mutect2, varscan2
- OR6N1 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.81); PolyPhen benign (0.404); catalogued as rs778798865, COSV58647423, COSV58647736; called by muse, mutect2, varscan2
- PAPPA2 | c.4507A>G p.S1503G | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV62793511; called by muse, mutect2, varscan2
- PCDHB6 | c.1786C>A p.Q596K | Missense Mutation (SNP) | VAF 51/117 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV99170242; called by muse, mutect2, varscan2
- PDGFC | c.250G>A p.V84I | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as COSV56846815; called by muse, mutect2, varscan2
- PI15 | c.86A>T p.D29V | Missense Mutation (SNP) | VAF 124/237 reads (52%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV52640309; called by muse, mutect2, varscan2
- PNLIPRP1 | c.1147A>T p.N383Y | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV62611251; called by muse, mutect2, varscan2
- PPP1R26 | c.1522G>T p.A508S | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.196); catalogued as rs142927502, COSV63355066; called by muse, mutect2, varscan2
- PREX2 | c.463C>T p.R155W | Missense Mutation (SNP) | VAF 63/146 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs139157434; called by muse, mutect2, varscan2
- PSMC2 | c.99G>C p.L33F | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV53006863; called by muse, mutect2, varscan2
- PXN | c.458A>T p.N153I | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57217823; called by muse, mutect2, varscan2
- RACGAP1 | c.1864C>A p.Q622K | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.628); catalogued as COSV56698841; called by muse, mutect2, varscan2
- RNF217 | c.1523G>A p.G508E (on ENST00000521654 / NM_001286398.2; = p.G216E on NM_152553.5) | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV51575101; called by muse, mutect2, varscan2
- ROBO2 | c.3403C>T p.R1135* | Nonsense Mutation (SNP) | VAF 36/80 reads (45%) | catalogued as COSV59899491; called by muse, mutect2, varscan2
- RPLP2 | c.232G>T p.G78C | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); catalogued as rs370189970; called by muse, mutect2, varscan2
- SCYL3 | c.1928A>C p.Q643P (on ENST00000367770; = p.Q589P on NM_020423.7) | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV53677430; called by muse, mutect2, varscan2
- SEMA5B | c.3020G>A p.R1007H | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs916876645, COSV52093569; called by muse, mutect2, varscan2
- SENP1 | c.1227del p.G410Vfs*4 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | catalogued as rs750651342; called by mutect2, varscan2
- SHCBP1L | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.988); catalogued as rs759840752, COSV62353918; called by muse, mutect2, varscan2
- SIM1 | c.404A>T p.E135V | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53490197; called by muse, mutect2, varscan2
- SIPA1L1 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.987); catalogued as rs146483394; called by muse, mutect2, varscan2
- SLC44A3 | c.1252C>G p.P418A (on ENST00000271227 / NM_001114106.3; = p.P370A on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.829); catalogued as COSV54728528; called by muse, mutect2, varscan2
- SOHLH2 | c.713C>T p.A238V | Missense Mutation (SNP) | VAF 52/81 reads (64%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs1333483864, COSV65901238; called by muse, mutect2, varscan2
- STARD3NL | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.088); catalogued as rs749040997, COSV50518108; called by muse, mutect2, varscan2
- STK40 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.971); catalogued as COSV63735029; called by muse, mutect2, varscan2
- STXBP3 | c.1006C>T p.H336Y | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV64181828; called by muse, mutect2, varscan2
- TNFRSF9 | c.643C>T p.R215W | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs143524950; called by muse, mutect2, varscan2
- TRIL | c.1414G>A p.A472T | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV59866791; called by muse, mutect2, varscan2
- TRIM7 | c.1243C>T p.R415C | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51241091; called by muse, mutect2
- TRPS1 | c.387A>C p.Q129H (on ENST00000220888 / NM_001330599.2; = p.Q142H on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.188); catalogued as COSV55231709; called by muse, mutect2, varscan2
- UBR4 | c.8627C>T p.A2876V | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs751701428, COSV64385160; called by muse, mutect2, varscan2
- VPS13D | c.867C>A p.F289L | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.062); catalogued as COSV62527121, COSV62534234; called by muse, mutect2, varscan2
- VWC2L | c.386T>A p.F129Y | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56967530; called by muse, mutect2, varscan2
- WNT4 | c.919G>C p.E307Q | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.346); catalogued as COSV51603074, COSV51605269; called by muse, mutect2, varscan2
- ZNF518A | c.2446T>A p.S816T | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV60150768; called by muse, mutect2, varscan2
- ZNF777 | c.1648G>A p.E550K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.359); catalogued as COSV56096767; called by muse, mutect2, varscan2
- ZZEF1 | c.7544G>A p.R2515Q | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.671); catalogued as rs139593441; called by muse, mutect2
- CENPO | c.370_381del p.V124_S127del | In Frame Del (DEL) | VAF 57/176 reads (32%) | called by mutect2, pindel, varscan2
- DISP1 | c.4261_4262del p.D1421Rfs*11 | Frame Shift Del (DEL) | VAF 31/116 reads (27%) | called by pindel, varscan2
- PRKN | c.873_874insA p.G292Rfs*8 | Frame Shift Ins (INS) | VAF 27/67 reads (40%) | called by mutect2, pindel, varscan2
- ST6GALNAC3 | c.88_96del p.E30_N32del | In Frame Del (DEL) | VAF 11/83 reads (13%) | called by mutect2, pindel
- VCX3B | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.515); called by mutect2, varscan2
- ACTL9 | c.717C>T p.A239= | Silent (SNP) | VAF 29/72 reads (40%) | catalogued as COSV61005209; called by muse, mutect2, varscan2
- AJAP1 | c.1071T>C p.S357= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV65449730; called by muse, mutect2, varscan2
- ATP11C | c.1281C>T p.C427= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV59560926; called by muse, mutect2, varscan2
- BUB1 | c.1575T>A p.S525= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV57062096; called by muse, mutect2, varscan2
- CALCOCO1 | c.1686C>T p.S562= | Silent (SNP) | VAF 24/123 reads (20%) | catalogued as COSV50412525; called by muse, mutect2, varscan2
- CCDC151 | c.1776T>G p.S592= | Silent (SNP) | VAF 8/124 reads (6%) | catalogued as COSV62697478; called by muse, mutect2
- CCL8 | c.165C>A p.T55= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV67013894; called by muse, mutect2, varscan2
- DCUN1D4 | c.798C>T p.L266= (on ENST00000334635 / NM_001287757.1; = p.L231= on NM_015115.3) | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as COSV58121561; called by muse, mutect2, varscan2
- DNAH9 | c.2334T>G p.T778= | Silent (SNP) | VAF 56/83 reads (67%) | catalogued as COSV52340692; called by muse, mutect2, varscan2
- DPEP1 | c.174G>A p.L58= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as COSV55359450; called by muse, mutect2, varscan2
- EPHA5 | c.1197C>T p.N399= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV56636925; called by muse, mutect2, varscan2
- ESS2 | c.309G>A p.V103= | Silent (SNP) | VAF 46/103 reads (45%) | catalogued as COSV52816519; called by muse, mutect2, varscan2
- FBN1 | c.4164C>T p.R1388= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV57312551; called by muse, mutect2, varscan2
- FBXO46 | c.1251C>T p.D417= | Silent (SNP) | VAF 9/111 reads (8%) | catalogued as rs1470014886, COSV58347975; called by muse, mutect2
- GDF7 | c.1191C>T p.I397= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as rs778037018, COSV55347332; called by muse, mutect2, varscan2
- GDNF | c.63G>A p.P21= | Silent (SNP) | VAF 27/178 reads (15%) | catalogued as COSV58478819; called by muse, mutect2, varscan2
- GPIHBP1 | c.522C>T p.A174= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs749855006, COSV58209078; called by muse, mutect2
- KCTD8 | c.768C>T p.R256= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV63586952; called by muse, mutect2, varscan2
- KLK8 | c.576C>A p.I192= | Silent (SNP) | VAF 23/87 reads (26%) | catalogued as COSV51591181; called by muse, mutect2, varscan2
- KRT25 | c.777C>T p.Y259= | Silent (SNP) | VAF 50/187 reads (27%) | catalogued as rs1209760960, COSV56444202; called by muse, mutect2, varscan2
- KRT26 | c.456C>T p.T152= | Silent (SNP) | VAF 10/103 reads (10%) | catalogued as COSV59413390; called by muse, mutect2, varscan2
- LRRC52 | c.567C>T p.N189= | Silent (SNP) | VAF 30/163 reads (18%) | catalogued as COSV54231613; called by muse, mutect2, varscan2
- MYO18B | c.6906G>A p.S2302= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as rs377507564; ClinVar: likely benign; called by muse, mutect2, varscan2
- OR8H1 | c.792T>C p.S264= | Silent (SNP) | VAF 37/71 reads (52%) | catalogued as rs1565100103, COSV57293471; called by muse, mutect2, varscan2
- SERPINA10 | c.516T>C p.F172= | Silent (SNP) | VAF 23/113 reads (20%) | catalogued as COSV56227770; called by muse, mutect2, varscan2
- SGK1 | c.312C>T p.I104= | Silent (SNP) | VAF 18/174 reads (10%) | catalogued as rs1015971626, COSV52806102; called by muse, mutect2, varscan2
- SHISA3 | c.498G>A p.T166= | Silent (SNP) | VAF 66/128 reads (52%) | catalogued as COSV59979478, COSV59979641; called by muse, mutect2, varscan2
- SPEF2 | c.1215A>G p.K405= | Silent (SNP) | VAF 61/75 reads (81%) | catalogued as COSV56795533; called by muse, mutect2, varscan2
- TDRD6 | c.1746C>T p.D582= | Silent (SNP) | VAF 17/220 reads (8%) | catalogued as rs143534526; called by muse, mutect2
- TLR9 | c.2784T>C p.Y928= | Silent (SNP) | VAF 52/161 reads (32%) | catalogued as rs1297156884, COSV62346009; called by muse, mutect2, varscan2
- TNIK | c.2769T>C p.F923= | Silent (SNP) | VAF 21/270 reads (8%) | catalogued as COSV52677363; called by muse, mutect2
- TNKS2 | c.759T>G p.S253= | Silent (SNP) | VAF 33/144 reads (23%) | catalogued as COSV65415072; called by muse, mutect2, varscan2
- ZSWIM8 | c.300G>A p.V100= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV67131745, COSV67132288; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65498989 T>G | 5'Flank (SNP) | VAF 34/156 reads (22%) | catalogued as rs754397792; called by muse, mutect2, varscan2
- ZNF658B | n.1211T>G | RNA (SNP) | VAF 67/324 reads (21%) | called by muse, mutect2, varscan2
